Somatic mutation profile of tumor specimen BA2123D (aliquot aq-BA2123D) from BEATAML1.0 case 2000, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.1 years (23,784 days).
Specimen BA2123D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19341c98-62f9-4d3b-ab0b-cde1502f6cb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2167D (Solid Tissue Normal), aliquot aq-BA2167D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeec63ea-087e-483a-9512-630bc752f877

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APP | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as rs201454946; called by muse, mutect2, varscan2
- BTN1A1 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs778241200, COSV104391218; called by muse, mutect2, varscan2
- CASC3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs771037006, COSV52868285; called by muse, varscan2
- DNMT3A | c.890G>A p.W297* | Nonsense Mutation (SNP) | VAF 32/64 reads (50%) | catalogued as rs944608317, COSV53073228; called by mutect2, varscan2
- RER1 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs199699910, COSV60383005; called by muse, mutect2, varscan2
- SMC3 | c.1982G>C p.R661P | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62421429, COSV62423179; called by muse, mutect2, varscan2
- WT1 | c.1359C>G p.H453Q | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.39); catalogued as COSV60070992, COSV60087055; called by muse, mutect2, varscan2
- CACUL1 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ENDOU | c.808C>G p.L270V (on ENST00000422538 / NM_001172439.2; = p.L229V on NM_006025.4) | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OGA | c.2633G>A p.C878Y | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PLPPR1 | c.132T>A p.H44Q | Missense Mutation (SNP) | VAF 177/390 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- RFX4 | c.1004C>T p.T335I (on ENST00000392842 / NM_213594.3; = p.T241I on NM_032491.6) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, varscan2
- F13B | c.1119G>A p.S373= | Silent (SNP) | VAF 110/243 reads (45%) | catalogued as rs748779845, COSV66373174; called by muse, mutect2, varscan2
- FUT2 | c.525G>C p.R175= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs548254465, COSV67179665; called by muse, mutect2
- MAGEL2 | c.1005T>C p.P335= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, varscan2
- PADI2 | c.1485G>A p.S495= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as rs779905920, COSV64945997; called by muse, varscan2
- PCLO | c.4935C>T p.Y1645= | Silent (SNP) | VAF 61/158 reads (39%) | called by muse, mutect2, varscan2
